TCGA case TCGA-34-2604 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cee6e9f6-6d7e-4096-a9bc-2cce004fb218

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 81 years; Vital status: Dead; Days to death: 958 days (2.6 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 81.7 years (29,827 days); Year of diagnosis: 1999; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 958 days (2.6 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 132; Tobacco smoking onset year: 1933.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-34-2604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-34-2604-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
  Slide TCGA-34-2604-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
- Sample TCGA-34-2604-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-34-2604-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1.2; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Lower; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -1011.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of acceptable prior treatment related to a prior/other malignancy: Prior malignancy bladder cancer treated w/ locoregional radiation.
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 958 days; disease-specific survival: no event (censored), 958 days; disease-free interval: no event (censored), 958 days; progression-free interval: no event (censored), 958 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-34-2604-01A-01D-0844-01): tumor purity 0.24, ploidy 2.81, whole-genome doublings 1.
